Somatic mutation profile of cancer-model specimen HCM-CSHL-0179-C25-85A (3D Organoid; aliquot HCM-CSHL-0179-C25-85A-01D-A78T-36), derived from the primary tumor of HCMI case HCM-CSHL-0179-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.3 years (22,008 days).
Specimen HCM-CSHL-0179-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9112d304-fc07-4e7d-a40c-b35473c98ce6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0179-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0179-C25-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61d5e6b4-b7f0-4368-a9c7-82c0990ad9b1

The open-access MAF lists 73 somatic variants for this specimen: 54 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 13, RNA 4, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, In Frame Ins 1, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH23 | c.6442G>A p.D2148N | Missense Mutation (SNP) | VAF 318/484 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs111033271, CM021546; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 194/424 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TAT | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 293/665 reads (44%) | catalogued as rs118203914, CM920661, COSV63532532; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 420/422 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs200778107; called by muse, mutect2, varscan2
- ADGRB3 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 101/199 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs113677156, COSV65405340; called by muse, mutect2, varscan2
- ALPP | c.179T>A p.I60N | Missense Mutation (SNP) | VAF 112/538 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs759881416; called by muse, varscan2
- CD276 | c.1120C>T p.R374W (on ENST00000318443 / NM_001024736.2; = p.R156W on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754785892, COSV100573437; called by muse, varscan2
- CNTN5 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs201144555, COSV54301785; called by muse, mutect2, varscan2
- COL11A1 | c.4131A>T p.K1377N | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV62192406; called by muse, mutect2, varscan2
- CROCC2 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 17/346 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as rs1370943085; called by muse, mutect2
- CTNND2 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773745550, COSV58868584; called by muse, mutect2, varscan2
- CUL9 | c.4597G>A p.A1533T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146080256; called by mutect2, varscan2
- DCUN1D5 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 78/138 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs756206539; called by muse, mutect2, varscan2
- FAM241B | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 167/532 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as rs1016187687; called by muse, mutect2, varscan2
- GLI2 | c.2000C>T p.P667L (on ENST00000361492 / NM_001374353.1; = p.P684L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/237 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as rs373968370; called by muse, mutect2, varscan2
- HTR1A | c.555C>G p.D185E | Missense Mutation (SNP) | VAF 175/782 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV100108888; called by muse, mutect2, varscan2
- IRX2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV57412579; called by muse, mutect2, varscan2
- LRFN1 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1282656157, COSV99953486; called by muse, mutect2
- MDM2 | c.961dup p.L321Pfs*13 | Frame Shift Ins (INS) | VAF 36/73 reads (49%) | catalogued as rs746910913; called by mutect2, varscan2
- MYO18A | c.3769C>T p.R1257W | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566347249; called by muse, mutect2, varscan2
- OR51B6 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs112049705, COSV66512594; called by muse, mutect2, varscan2
- OR5J2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV56622888; called by muse, mutect2
- PODN | c.1919G>A p.R640H (on ENST00000395871; = p.R592H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs750891509, COSV57014653; called by mutect2, varscan2
- PTPRO | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 197/431 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55523950; called by muse, mutect2, varscan2
- RFPL1 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs542404003; called by muse, mutect2, varscan2
- SEC13 | c.647G>A p.R216Q (on ENST00000350697 / NM_183352.3; = p.R219Q on NM_030673.4) | Missense Mutation (SNP) | VAF 142/228 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs754016117, COSV99046690; called by muse, mutect2, varscan2
- SEZ6L | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.427); catalogued as rs760398959, COSV50690159; called by muse, mutect2, varscan2
- SHCBP1L | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 106/647 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs754623560; called by muse, varscan2
- SIGLEC7 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 44/622 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs771229132, COSV99978326; called by muse, mutect2
- SLC22A10 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 202/320 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs200183991; called by muse, mutect2, varscan2
- SPEG | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs775824354, COSV56673806; called by mutect2, varscan2
- TARM1 | c.260C>T p.A87V (on ENST00000616041 / NM_001330650.1; = p.A79V on NM_001135686.3) | Missense Mutation (SNP) | VAF 150/1316 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs758163798, COSV101444635, COSV71524932; called by muse, mutect2, varscan2
- TENM3 | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 93/152 reads (61%) | SIFT tolerated (0.38); PolyPhen benign (0.258); catalogued as rs759712953, COSV69315835; called by muse, mutect2, varscan2
- TSPAN5 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762215531, COSV59879415; called by muse, mutect2, varscan2
- UMOD | c.152C>A p.T51N | Missense Mutation (SNP) | VAF 171/637 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs778464982; called by muse, mutect2, varscan2
- VWA5B1 | c.468C>A p.S156R | Missense Mutation (SNP) | VAF 118/362 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs562282893, COSV57061584; called by muse, mutect2, varscan2
- ACVR1B | c.634_635del p.I212Yfs*18 | Frame Shift Del (DEL) | VAF 76/109 reads (70%) | called by mutect2, pindel
- ADCY2 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CCNDBP1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 17/487 reads (3%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2
- CDKN2A | c.291_292del p.H98Pfs*21 | Frame Shift Del (DEL) | VAF 394/584 reads (67%) | called by pindel, varscan2
- INSRR | c.2639T>C p.L880P | Missense Mutation (SNP) | VAF 16/454 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.959); called by muse, mutect2
- KLHL1 | c.1258T>A p.F420I | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.061); called by muse, mutect2
- LRBA | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.766); called by mutect2, varscan2
- MAST2 | c.4892C>G p.S1631C | Missense Mutation (SNP) | VAF 99/304 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYT1L | c.2452C>A p.P818T | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- NPIPB2 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 353/825 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNLIPRP1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 134/224 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- POU4F2 | c.177_178insAGC p.G59_G60insS | In Frame Ins (INS) | VAF 38/246 reads (15%) | called by mutect2, pindel
- PPP1R21 | c.116C>G p.A39G | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SMIM21 | c.261-2A>T p.X87_splice | Splice Site (SNP) | VAF 138/207 reads (67%) | called by muse, mutect2, varscan2
- TFAP2B | c.219del p.Y74Tfs*22 | Frame Shift Del (DEL) | VAF 65/324 reads (20%) | called by mutect2, pindel, varscan2
- WDR97 | c.2307G>A p.K769= | Splice Region (SNP) | VAF 100/334 reads (30%) | called by muse, mutect2, varscan2
- XPO5 | c.383G>A p.W128* | Nonsense Mutation (SNP) | VAF 92/135 reads (68%) | called by muse, mutect2, varscan2
- ADAD1 | c.162G>A p.T54= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as rs139626702; called by muse, mutect2, varscan2
- AHNAK | c.14997T>G p.T4999= | Silent (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- ALPP | c.1380G>A p.A460= | Silent (SNP) | VAF 244/837 reads (29%) | catalogued as rs1261155097; called by muse, mutect2, varscan2
- IPO4 | c.2502C>T p.H834= | Silent (SNP) | VAF 59/301 reads (20%) | catalogued as rs767137886, COSV61016614; called by muse, mutect2, varscan2
- KIDINS220 | c.1239C>T p.S413= | Silent (SNP) | VAF 45/152 reads (30%) | called by muse, mutect2, varscan2
- LAMC3 | c.546C>T p.G182= | Silent (SNP) | VAF 332/335 reads (99%) | catalogued as rs771073233, COSV63094599; called by muse, mutect2, varscan2
- MDN1 | c.6201A>T p.P2067= | Silent (SNP) | VAF 175/409 reads (43%) | called by muse, mutect2, varscan2
- MFSD2B | c.660A>C p.P220= | Silent (SNP) | VAF 34/182 reads (19%) | called by muse, varscan2
- MYO15A | c.1671C>T p.F557= | Silent (SNP) | VAF 74/378 reads (20%) | catalogued as rs879619613, COSV99234779; called by muse, mutect2, varscan2
- PCDHGA11 | c.1644G>A p.S548= | Silent (SNP) | VAF 154/579 reads (27%) | catalogued as rs769543752, COSV53947486, COSV53984994; called by muse, mutect2, varscan2
- SLC13A4 | c.1515C>T p.T505= | Silent (SNP) | VAF 40/261 reads (15%) | catalogued as rs772841017, COSV100818826; called by muse, mutect2, varscan2
- TNRC6B | c.1092G>A p.Q364= | Silent (SNP) | VAF 84/221 reads (38%) | called by muse, mutect2, varscan2
- ZNF557 | c.1209G>T p.G403= (on ENST00000414706 / NM_001044388.2; = p.G410= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- FAM90A20P | n.1203C>T | RNA (SNP) | VAF 131/631 reads (21%) | catalogued as rs1443663189; called by muse, mutect2, varscan2
- GBA3 | c.59-8111T>A | Intron (SNP) | VAF 56/162 reads (35%) | called by muse, mutect2, varscan2
- LINC00299 | n.2149C>T | RNA (SNP) | VAF 28/286 reads (10%) | called by muse, mutect2
- MIR99AHG | n.622A>T | RNA (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- OSBPL8 | c.218-11943G>A | Intron (SNP) | VAF 82/185 reads (44%) | called by muse, mutect2, varscan2
- RPS26P15 | n.275G>A | RNA (SNP) | VAF 82/318 reads (26%) | catalogued as rs768731084; called by muse, mutect2, varscan2
